Surgical pathology report (de-identified scan), TCGA case TCGA-29-2414, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2414-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-2414

Surg Path

CLINICAL HISTORY:

Ovaries look normal, omental cake, ? primary.

GROSS EXAMINATION:

A. "Omentum (Afl)", received fresh. The specimen consists of a 15.0 x 12.9 x 1.6 cm fragment of yellow/pink adipose tissue. The cut section discloses firm, yellow/gray tumor. A portion has been submitted for frozen section as Afl with the frozen section submitted in toto in block A1. Additional sections of the tumor are submitted in blocks A2-3.

B. "Left ovary", fresh. The specimen consists of a 3 gm, 1.7 x 1.2 x 0.7 cm ovary with an attached 3.0 cm segment of fallopian tube with an average diameter of 0.4 cm. On the surface of the ovary is a 0.6 x 0.5 x 0.4 cm pink/red excrescences. Cut sectioning of the ovary discloses normal parenchyma (B1). Adherent to the fallopian tube is a similar 1.0 x 0.8 x 0.5 cm pink/red excrescences (B2).

C. "Right ovary", fresh. The specimen consists of a 3.5 gm, 1.9 x 1.0 x 0.7 cm ovary with an attached 4.0 cm segment of fimbriated fallopian tube with an average diameter of 0.4 cm. Cut section of the ovary discloses a 0.7 cm unilocular cyst which is filled by a calcified secretion and the wall has gray/pink focal papillations (C1). There is a 0.3 cm in diameter paratubal cyst and the fallopian tube is unremarkable. The remaining adherent connective tissue is unremarkable (C2).

D. "Uterus and cervix", fresh. The specimen has been received laterally opened. It consists of a 35.6 gm, 5.0 x 3.5 x 2.5 cm uterine body with a 3.0 x 1.5 cm cervix having a cervical os of 0.5 cm. On the serosa of the anterior corpus is a 2.0 x 1.0 x 1.0 cm mass of hemorrhagic connective tissue covered with pink/red excrescences. Adjacent to this mass is a 0.3 x 0.2 cm serosal plaque and a 0.7 cm in diameter leiomyoma which on cut section discloses a whorled pattern with no hemorrhage or necrosis. The myometrium has uniform thickness of 0.9 cm, the endometrium a uniform thick of 0.15 cm, and are both unremarkable. The cervix is diffusely erythematous with numerous nabothian cysts and is unremarkable. Sections of the serosal mass are submitted in D1, leiomyoma and serosal plaque in D2, anterior cervix D3, posterior cervix D4, anterior endometrium D5, and posterior endometrium in D6.

E. "Umbilical nodule", fresh. The specimen consists of two yellow/pink tissue fragments covered with gray/white excrescences, 2.5 x 1.5 x 0.9 cm and 0.9 x 0.8 x 0.5 cm. The larger fragment is bisected and completely submitted in block E1 and the smaller fragment submitted in toto in block E2.

INTRA OPERATIVE CONSULTATION:

A. "Omentum": Afl - adenocarcinoma.

DIAGNOSIS:

B. LEFT OVARY:

SEROUS ADENOCARCINOMA, FIGO GRADE 2
WITH IMPLANTS TO:

A. OMENTUM

D. UTERINE SEROSA, FOCAL

E. UMBILICAL NODULE

THE FOLLOWING ARE FREE OF TUMOR:

C. RIGHT OVARY: ADHESION, SMALL

[page 2 of 2]
D. UTERUS

ENDOMETRIUM: ATROPHY WITH SMALL SESSILE POL
MYOMETRIUM & CERVIX: NO PATHOLOGIC DIAGNOSI

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 39fd4515-ffe6-4c66-b6dc-b627a28727a7 (TCGA-29-2414.C480EE08-D996-40E6-BD86-3E614625D98B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).